Somatic mutation profile of tumor specimen HCM-SANG-0271-D12-31B (aliquot HCM-SANG-0271-D12-31B-01D-A80U-36) from HCMI case HCM-SANG-0271-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubular adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0271-D12-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e876777c-d36e-49c4-a87f-70717a156667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0271-D12-10A (Blood Derived Normal), aliquot HCM-SANG-0271-D12-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d0cee86-2a53-4dbb-84ee-4b80c9b4a21f

The open-access MAF lists 177 somatic variants for this specimen: 126 protein-altering or splice-affecting, 43 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 43, Nonsense Mutation 11, Intron 5, In Frame Del 2, Frame Shift Del 2, Splice Region 2, Splice Site 2, 3'UTR 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3186_3187del p.S1063* | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | catalogued as rs1060503362; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 112/381 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 146/428 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- ADAMTS13 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 209/713 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs782511560; called by muse, mutect2, varscan2
- ADCY9 | c.3518C>T p.T1173M | Missense Mutation (SNP) | VAF 139/632 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1371707087, COSV53572532; called by muse, mutect2, varscan2
- AKIRIN1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1315318370; called by muse, mutect2, varscan2
- ALK | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 87/527 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs745499366, COSV66577674; ClinVar: uncertain significance; called by muse, varscan2
- ATP13A5 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1393318983; called by muse, mutect2
- B3GALT5 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1454210645; called by muse, mutect2, varscan2
- BIRC6 | c.13730G>A p.R4577H | Missense Mutation (SNP) | VAF 246/491 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428256; called by muse, mutect2, varscan2
- CCN5 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 196/2320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778811911; called by muse, mutect2
- COL12A1 | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 12/292 reads (4%) | catalogued as COSV100485159, COSV59401096; called by muse, mutect2
- CSMD3 | c.7032C>G p.D2344E (on ENST00000297405 / NM_001363185.1; = p.D2240E on NM_052900.3) | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV52334770; called by muse, mutect2, varscan2
- CXCR4 | c.82T>A p.C28S | Missense Mutation (SNP) | VAF 96/380 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54009986; called by muse, mutect2, varscan2
- DCDC1 | c.3394C>A p.L1132I (on ENST00000597505 / NM_001367979.1; = p.L239I on NM_020869.3) | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as COSV60305246, COSV60308419; called by muse, mutect2
- DNAH10 | c.9794C>A p.S3265* (on ENST00000409039; = p.S3204* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 40/702 reads (6%) | catalogued as COSV68987714; called by muse, mutect2
- DOK7 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 346/595 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs769289951; called by muse, mutect2, varscan2
- EPHA3 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs773476878, COSV60719749; called by muse, mutect2, varscan2
- ERICH4 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 179/429 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs782111142; called by muse, mutect2, varscan2
- ERVMER34-1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1051087038; called by muse, mutect2, varscan2
- FAM110A | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 207/1115 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs957098379; called by muse, mutect2, varscan2
- FOSB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1180159338; called by muse, mutect2
- H2BC11 | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs769130601; called by muse, mutect2, varscan2
- HECTD1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 69/109 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1200713364, COSV67947686; called by muse, mutect2, varscan2
- HK3 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 127/449 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771626485, COSV52842984; called by muse, mutect2, varscan2
- HRNR | c.1699A>T p.R567W | Missense Mutation (SNP) | VAF 136/536 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as rs1191808120, COSV64255120; called by muse, varscan2
- IGSF10 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs374510873, COSV99193968; called by muse, varscan2
- IRS4 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 37/670 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433867608, COSV64532727, COSV64535800; called by muse, mutect2
- ITPR2 | c.3558G>T p.L1186F | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371072511; called by muse, mutect2
- KCNB2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 69/426 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV73050947, COSV73053233; called by muse, mutect2, varscan2
- KCNMA1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 121/394 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54237087, COSV54243900; called by muse, mutect2, varscan2
- KIF19 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 137/546 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs765728283, COSV63428708; called by muse, mutect2, varscan2
- KRR1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs549769836, COSV56991708; called by muse, mutect2, varscan2
- KRT23 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 208/659 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs750245687, COSV52926972, COSV52929212; called by muse, mutect2, varscan2
- LZTR1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 169/511 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs970027059, COSV99301246; called by muse, mutect2, varscan2
- MAGEA12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 19/558 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1556833500, COSV100757013, COSV63295146; called by muse, mutect2
- MAGEB10 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs754281513; called by muse, mutect2, varscan2
- MAGEB6B | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1046848646; called by muse, mutect2
- MBNL2 | c.727A>C p.K243Q | Missense Mutation (SNP) | VAF 307/810 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.501); catalogued as COSV59117309; called by muse, mutect2, varscan2
- MINAR1 | c.2299-1G>C p.X767_splice | Splice Site (SNP) | VAF 19/363 reads (5%) | catalogued as COSV59586069; called by muse, mutect2
- MYH14 | c.2975C>T p.T992M | Missense Mutation (SNP) | VAF 187/461 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs201746408, COSV51826998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.4402G>C p.E1468Q | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs755024942; called by muse, mutect2, varscan2
- NBR1 | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV57835849; called by muse, mutect2, varscan2
- OCSTAMP | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 267/1625 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs868469717, COSV99645009; called by muse, mutect2, varscan2
- PIK3C2A | c.2431C>A p.L811I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as rs139656286; called by muse, mutect2, varscan2
- PIK3C2G | c.916T>C p.C306R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1454100925; called by muse, mutect2
- PLXNA4 | c.4029C>A p.Y1343* | Nonsense Mutation (SNP) | VAF 58/420 reads (14%) | catalogued as COSV100325046; called by mutect2, varscan2
- PTPRS | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 227/705 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1224185745; called by muse, mutect2, varscan2
- RRAGC | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 74/110 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs761415462, COSV65931302; called by muse, mutect2, varscan2
- SIX6 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 184/547 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs886050563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO3A1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 251/746 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV59229085; called by muse, mutect2, varscan2
- SSH3 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 143/550 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200078645; called by muse, mutect2, varscan2
- SUFU | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 131/424 reads (31%) | catalogued as COSV64014466; called by muse, mutect2, varscan2
- TCF4 | c.525A>C p.K175N | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV61891740; called by muse, mutect2
- TDRD9 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 213/329 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs781139035; called by muse, mutect2, varscan2
- THNSL1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1289647382, COSV64479532; called by muse, mutect2
- TNFRSF11A | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1020903615, COSV54022728; called by muse, mutect2
- TPO | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 196/1074 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs1173922703; called by muse, mutect2
- TSPAN1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64339535; called by muse, mutect2
- URGCP | c.682C>A p.L228M (on ENST00000453200 / NM_001077663.3; = p.L219M on NM_017920.4) | Missense Mutation (SNP) | VAF 21/752 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.64); catalogued as COSV56250117; called by muse, mutect2
- ZC3H12C | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1256899304; called by muse, mutect2, varscan2
- ZFPM2 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 209/512 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770304470; called by muse, mutect2, varscan2
- ZNF614 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778179613; called by muse, mutect2, varscan2
- AASS | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- AATK | c.2415G>C p.E805D (on ENST00000326724 / NM_001080395.3; = p.E702D on NM_004920.2) | Missense Mutation (SNP) | VAF 315/699 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACVR1C | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 18/582 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- ADARB2 | c.1683-8C>A | Splice Region (SNP) | VAF 447/693 reads (65%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3380C>A p.T1127N | Missense Mutation (SNP) | VAF 46/581 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ADGRG4 | c.3995C>A p.P1332H | Missense Mutation (SNP) | VAF 30/509 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2
- APOB | c.1622A>T p.Q541L | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- BRWD3 | c.2961G>T p.K987N | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC168 | c.8731C>T p.Q2911* | Nonsense Mutation (SNP) | VAF 36/258 reads (14%) | called by muse, mutect2, varscan2
- CHD4 | c.5083_5086+1dup p.X1695_splice (on ENST00000357008 / NM_001363606.2; = p.X1706_splice on NM_001273.5) | Splice Site (INS) | VAF 103/220 reads (47%) | called by mutect2, pindel, varscan2
- CLEC5A | c.46A>C p.K16Q | Missense Mutation (SNP) | VAF 83/483 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CNNM1 | c.544A>C p.K182Q | Missense Mutation (SNP) | VAF 44/852 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- COX7A2 | c.176A>T p.K59I | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CRYBG3 | c.4987G>T p.V1663F | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- DAPK3 | c.451A>G p.N151D | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- DOK5 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 83/928 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2
- ERC2 | c.19A>C p.T7P | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FREM3 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 32/1190 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2
- GBP7 | c.1528A>T p.K510* | Nonsense Mutation (SNP) | VAF 88/314 reads (28%) | called by muse, mutect2, varscan2
- GPI | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 120/627 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC12 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- HDAC4 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 39/429 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- HMCN1 | c.1343A>C p.Q448P | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- HSP90AA1 | c.449_450del p.V150Dfs*5 | Frame Shift Del (DEL) | VAF 92/430 reads (21%) | called by pindel, varscan2
- KCND1 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 238/584 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCTD9 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- LARGE1 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 35/519 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- LRRC9 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- LYZL1 | c.285C>A p.C95* (on ENST00000375500; = p.C49* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 128/392 reads (33%) | called by muse, mutect2, varscan2
- MAGEB4 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2
- MBD5 | c.4190C>A p.T1397N | Missense Mutation (SNP) | VAF 55/468 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MRPL38 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 144/726 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MRRF | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MYCBP2 | c.346G>A p.V116I (on ENST00000357337; = p.V154I on NM_015057.5) | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- OR10A6 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 64/459 reads (14%) | called by muse, mutect2, varscan2
- OR10J5 | c.84T>A p.F28L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5L2 | c.615G>C p.L205F | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA1 | c.2236G>T p.G746W | Missense Mutation (SNP) | VAF 138/442 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCMTD1 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PIKFYVE | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKM | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PLCB1 | c.3019G>C p.D1007H | Missense Mutation (SNP) | VAF 60/600 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- PRAME | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 141/417 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- PRR29 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 127/656 reads (19%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1362_1364del p.F454del (on ENST00000402538 / NM_001349975.2; = p.F453del on NM_015376.2 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 28/174 reads (16%) | called by pindel, varscan2
- RASSF10 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 408/910 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM46 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGL2 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 54/1026 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RNF6 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 54/626 reads (9%) | called by muse, mutect2
- SLAIN1 | c.1405T>C p.S469P (on ENST00000466548; = p.S206P on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/672 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- SYNGR2 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 198/970 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TAPBP | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 139/618 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TBC1D5 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TP53I11 | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 107/496 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRIM64 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TRPV1 | c.1044G>A p.G348= | Splice Region (SNP) | VAF 85/312 reads (27%) | called by muse, mutect2, varscan2
- VCAN | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- WDR75 | c.1984_1986del p.S662del | In Frame Del (DEL) | VAF 106/192 reads (55%) | called by mutect2, pindel, varscan2
- XPO1 | c.2554C>T p.L852F | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZBTB1 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 127/211 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZC3H11A | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- ZNF284 | c.1443A>C p.K481N | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF844 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, varscan2
- ADAMTS2 | c.2109C>T p.I703= | Silent (SNP) | VAF 85/305 reads (28%) | catalogued as rs200210415, COSV52375142; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- ADD2 | c.45G>A p.P15= | Silent (SNP) | VAF 98/622 reads (16%) | catalogued as COSV52469298; called by muse, mutect2, varscan2
- AK9 | c.2478C>T p.P826= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as rs958543521, COSV58139097, COSV58140680; called by muse, varscan2
- CALY | c.183G>A p.Q61= | Silent (SNP) | VAF 53/551 reads (10%) | called by muse, mutect2
- CCDC186 | c.1680G>A p.L560= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- CHST10 | c.270C>T p.N90= | Silent (SNP) | VAF 70/479 reads (15%) | catalogued as rs148626049, COSV99958968; called by muse, mutect2, varscan2
- CSMD1 | c.4767C>T p.Y1589= (on ENST00000520002; = p.Y1588= on NM_033225.6) | Silent (SNP) | VAF 113/429 reads (26%) | catalogued as rs1258606725; called by muse, mutect2, varscan2
- DLX5 | c.696G>T p.S232= | Silent (SNP) | VAF 119/800 reads (15%) | called by muse, mutect2, varscan2
- ELP2 | c.174C>T p.T58= | Silent (SNP) | VAF 20/215 reads (9%) | catalogued as rs150889303, COSV52369120; called by muse, mutect2
- FCRL4 | c.750C>T p.T250= | Silent (SNP) | VAF 291/483 reads (60%) | catalogued as rs775384031, COSV99619138; called by muse, mutect2, varscan2
- FIGN | c.1074C>T p.N358= | Silent (SNP) | VAF 157/695 reads (23%) | called by muse, mutect2, varscan2
- GDF6 | c.1014C>T p.F338= | Silent (SNP) | VAF 86/444 reads (19%) | catalogued as rs1474559057, COSV99747493; called by muse, mutect2, varscan2
- GGH | c.783A>T p.A261= | Silent (SNP) | VAF 62/332 reads (19%) | called by muse, mutect2, varscan2
- GOLM2 | c.96C>T p.Y32= | Silent (SNP) | VAF 176/598 reads (29%) | called by muse, mutect2, varscan2
- GPR132 | c.201G>A p.A67= | Silent (SNP) | VAF 374/577 reads (65%) | catalogued as rs575453416, COSV61677884; called by muse, mutect2, varscan2
- GPR32 | c.234C>A p.T78= | Silent (SNP) | VAF 148/626 reads (24%) | catalogued as rs771826086; called by muse, mutect2, varscan2
- HECTD4 | c.4401G>A p.T1467= | Silent (SNP) | VAF 156/398 reads (39%) | catalogued as rs533197509, COSV61180963; called by muse, mutect2, varscan2
- IFIT1 | c.552T>C p.S184= | Silent (SNP) | VAF 228/394 reads (58%) | called by muse, mutect2, varscan2
- IGSF10 | c.1878C>T p.N626= | Silent (SNP) | VAF 19/326 reads (6%) | catalogued as rs774029389; called by muse, mutect2
- KBTBD13 | c.969C>T p.Y323= | Silent (SNP) | VAF 182/568 reads (32%) | catalogued as rs568613948, COSV71351377; called by muse, mutect2, varscan2
- MAST1 | c.1182C>T p.R394= | Silent (SNP) | VAF 106/317 reads (33%) | catalogued as rs778656447, COSV52248363; called by muse, mutect2, varscan2
- MYH13 | c.1902C>G p.S634= | Silent (SNP) | VAF 66/249 reads (27%) | called by muse, mutect2, varscan2
- NACAD | c.3816G>A p.P1272= | Silent (SNP) | VAF 190/870 reads (22%) | catalogued as rs888779393, COSV101512091; called by muse, mutect2, varscan2
- NAT10 | c.2109C>T p.A703= | Silent (SNP) | VAF 242/538 reads (45%) | catalogued as rs779738249; called by muse, mutect2, varscan2
- NRIP1 | c.1029T>C p.A343= | Silent (SNP) | VAF 13/261 reads (5%) | called by muse, mutect2
- NXF3 | c.861G>A p.T287= | Silent (SNP) | VAF 147/413 reads (36%) | catalogued as rs201477119, COSV67702814; called by muse, mutect2, varscan2
- OR2H1 | c.261G>A p.K87= | Silent (SNP) | VAF 179/811 reads (22%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1392G>A p.V464= | Silent (SNP) | VAF 26/599 reads (4%) | called by muse, mutect2
- PDP1 | c.546C>T p.S182= | Silent (SNP) | VAF 168/601 reads (28%) | catalogued as rs202034256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITX1 | c.486G>A p.P162= | Silent (SNP) | VAF 40/548 reads (7%) | called by muse, mutect2
- PLXNA4 | c.4030C>A p.R1344= | Silent (SNP) | VAF 63/457 reads (14%) | catalogued as rs375720148; called by muse, mutect2, varscan2
- PLXNA4 | c.2943C>A p.A981= | Silent (SNP) | VAF 75/663 reads (11%) | called by muse, mutect2, varscan2
- POLR2H | c.102T>A p.S34= | Silent (SNP) | VAF 76/292 reads (26%) | called by muse, mutect2, varscan2
- PTPRT | c.1290C>T p.F430= | Silent (SNP) | VAF 191/1413 reads (14%) | called by muse, mutect2, varscan2
- RNF133 | c.351A>G p.K117= | Silent (SNP) | VAF 197/508 reads (39%) | called by muse, mutect2, varscan2
- RNF213 | c.14901C>A p.G4967= | Silent (SNP) | VAF 49/471 reads (10%) | catalogued as rs775932728; called by muse, mutect2, varscan2
- SDHA | c.117G>C p.G39= | Silent (SNP) | VAF 75/355 reads (21%) | catalogued as CD137030, COSV99371562; called by muse, mutect2, varscan2
- SLC15A3 | c.1626C>T p.F542= | Silent (SNP) | VAF 21/467 reads (4%) | called by muse, mutect2
- SSTR4 | c.297C>T p.S99= | Silent (SNP) | VAF 40/1080 reads (4%) | catalogued as COSV54797126; called by muse, mutect2
- TEX37 | c.111G>A p.T37= | Silent (SNP) | VAF 45/391 reads (12%) | catalogued as rs370424706; called by muse, mutect2, varscan2
- UBASH3B | c.447C>T p.T149= | Silent (SNP) | VAF 77/470 reads (16%) | catalogued as rs1211610353; called by muse, mutect2, varscan2
- ZIC1 | c.1026C>G p.R342= | Silent (SNP) | VAF 117/358 reads (33%) | called by muse, mutect2, varscan2
- ZNF564 | c.1599C>T p.Y533= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs376997794; called by muse, mutect2, varscan2
- DAPK2 | c.858+1789T>C | Intron (SNP) | VAF 91/323 reads (28%) | called by muse, mutect2, varscan2
- DNAH9 | c.904+32T>C | Intron (SNP) | VAF 135/432 reads (31%) | catalogued as rs774772560; called by muse, mutect2, varscan2
- KCNH5 | c.*1T>G | 3'UTR (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.29G>C | RNA (SNP) | VAF 107/546 reads (20%) | catalogued as rs535648212, COSV55601555; called by muse, mutect2, varscan2
- NUDT7 | c.190-326G>A | Intron (SNP) | VAF 85/244 reads (35%) | catalogued as rs965893001; called by muse, mutect2, varscan2
- SCNN1B | c.-9+1618C>T | Intron (SNP) | VAF 16/489 reads (3%) | catalogued as rs1040015244; called by muse, mutect2
- TNNI3 | c.-134G>T | 5'UTR (SNP) | VAF 25/799 reads (3%) | called by muse, mutect2
- ZNF665 | c.-54+10428G>C | Intron (SNP) | VAF 46/360 reads (13%) | called by muse, mutect2, varscan2
